Somatic mutation profile of tumor specimen TCGA-25-1312-01A (aliquot TCGA-25-1312-01A-01W-0492-08) from TCGA case TCGA-25-1312, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 69.9 years (25,537 days).
Specimen TCGA-25-1312-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6ec34b2f-40c5-409b-8ae3-0b6cfc52fbe6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-25-1312-10A (Blood Derived Normal), aliquot TCGA-25-1312-10A-01W-0492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/effa09c6-ea4d-4ba9-9971-bc93ff7df19e

The open-access MAF lists 17 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 4, RNA 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCL9 | c.1974G>A p.M658I | Missense Mutation (SNP) | VAF 52/176 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV52342838; called by muse, mutect2, varscan2
- CSMD3 | c.2458C>T p.R820C (on ENST00000297405 / NM_001363185.1; = p.R716C on NM_052900.3) | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52229650; called by muse, mutect2
- CUX1 | c.1942C>G p.R648G | Missense Mutation (SNP) | VAF 39/258 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV52890936, COSV99470307; called by muse, varscan2
- KLK8 | c.721G>A p.V241I | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs56296296; called by muse, mutect2, varscan2
- KSR1 | c.1486C>T p.H496Y (on ENST00000644974 / NM_001367810.1; = p.H359Y on NM_014238.2) | Missense Mutation (SNP) | VAF 228/318 reads (72%) | SIFT tolerated (0.47); PolyPhen benign (0.089); catalogued as COSV99257849; called by muse, varscan2
- N4BP2L2 | c.2282C>T p.S761L (on ENST00000674422; = p.S332L on NM_033111.4) | Missense Mutation (SNP) | VAF 84/155 reads (54%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV100678706; called by muse, mutect2, varscan2
- NRDC | c.3556C>G p.L1186V | Missense Mutation (SNP) | VAF 113/670 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.221); catalogued as COSV100542855; called by muse, varscan2
- PPP1R12A | c.965C>T p.T322M | Missense Mutation (SNP) | VAF 30/163 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs368235078; called by muse, mutect2, varscan2
- SLITRK1 | c.1972G>A p.A658T | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as rs1454656332, COSV65676452; called by muse, mutect2, varscan2
- TMPRSS15 | c.1346A>G p.K449R | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV99516730; called by mutect2, varscan2
- TP53 | c.629del p.N210Tfs*37 | Frame Shift Del (DEL) | VAF 149/225 reads (66%) | catalogued as CD921041, COSV52979868, COSV53339346; called by mutect2, pindel, varscan2
- BAX | c.265dup p.R89Pfs*10 | Frame Shift Ins (INS) | VAF 5/36 reads (14%) | called by mutect2, varscan2
- AFMID | c.438G>A p.A146= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as rs746788138, COSV100014802; called by muse, mutect2, varscan2
- ARHGAP10 | c.1971A>G p.P657= | Silent (SNP) | VAF 25/83 reads (30%) | catalogued as rs945018772, COSV100330844; called by muse, mutect2
- NLRP4 | c.1749C>T p.N583= | Silent (SNP) | VAF 80/124 reads (65%) | catalogued as rs201393247; called by muse, mutect2, varscan2
- ZBTB16 | c.1413G>A p.S471= | Silent (SNP) | VAF 21/138 reads (15%) | catalogued as rs202099154, COSV60101368; called by muse, varscan2
- SNORD116-17 | n.69G>A | RNA (SNP) | VAF 56/126 reads (44%) | catalogued as rs373622029; called by muse, mutect2, varscan2
